Somatic mutation profile of tumor specimen MMRF_2587_1_BM_CD138pos (aliquot MMRF_2587_1_BM_CD138pos_T1_KHS5U_L12857) from MMRF case MMRF_2587, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.0 years (26,649 days).
Specimen MMRF_2587_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68c6dc9b-a838-461e-9365-aa1f162140ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2587_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2587_1_PB_Whole_C3_KHS5U_L12856; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/403a2f90-e85a-4736-b291-6b8f1e1a09ad

The open-access MAF lists 176 somatic variants for this specimen: 76 protein-altering or splice-affecting, 20 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, 3'UTR 47, Intron 21, Silent 20, 5'UTR 7, Nonsense Mutation 6, 5'Flank 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNV2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754275640, CM1311095; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 111/302 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs782435064, COSV61006822; called by muse, mutect2, varscan2
- AMER3 | c.2263C>A p.L755I | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV58470507; called by muse, mutect2
- ANGPTL4 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100034996; called by muse, mutect2, varscan2
- CDC20B | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs936904047, COSV99696575; called by muse, mutect2, varscan2
- CDK2AP1 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs1463324847; called by muse, mutect2, varscan2
- CDS1 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); catalogued as rs761418360, COSV99881022; called by muse, mutect2, varscan2
- DMRT2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1279902278; called by muse, mutect2
- HGD | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV52198142; called by muse, mutect2, varscan2
- IGHV2-70 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 91/146 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs116618054; called by muse, varscan2
- IGHV2-70 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs755395069; called by muse, varscan2
- IGLV3-1 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs61731689; called by muse, varscan2
- IGLV3-1 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs368499668; called by muse, varscan2
- LZTR1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV53151927; called by muse, mutect2, varscan2
- MAGI1 | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as rs532649444; called by muse, mutect2, varscan2
- MERTK | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 27/221 reads (12%) | catalogued as COSV54925114; called by muse, mutect2, varscan2
- MME | c.2165C>A p.T722N | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs917938667; called by muse, mutect2, varscan2
- NPHS1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.616); catalogued as rs146400394; called by muse, mutect2, varscan2
- PDGFRA | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1368411882, COSV57266084, COSV57274531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDZD2 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 122/248 reads (49%) | catalogued as COSV56859928; called by muse, mutect2, varscan2
- PIK3R6 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs373694633, COSV100266337; called by muse, mutect2, varscan2
- PTPRB | c.4948C>T p.R1650* | Nonsense Mutation (SNP) | VAF 34/71 reads (48%) | catalogued as rs761019588, COSV54238469; called by muse, mutect2, varscan2
- RAB41 | c.21C>A p.D7E | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as rs1569223928; called by muse, mutect2, varscan2
- SCN11A | c.3614G>C p.G1205A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.239); catalogued as COSV56569607; called by muse, mutect2, varscan2
- SOSTDC1 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV61049935; called by muse, mutect2
- SSTR4 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs200321103, COSV54797974; called by muse, mutect2, varscan2
- STIM2 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 103/162 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs140734561; called by muse, mutect2, varscan2
- SYT14 | c.734C>A p.S245* | Nonsense Mutation (SNP) | VAF 88/210 reads (42%) | catalogued as COSV99656389; called by muse, mutect2, varscan2
- TKTL1 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 89/591 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV54213581; called by muse, mutect2, varscan2
- TMEM64 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1446063345; called by muse, mutect2, varscan2
- TPP2 | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV65752374; called by muse, mutect2, varscan2
- USP21 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 95/619 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.95); catalogued as rs757075486; called by muse, mutect2, varscan2
- ZBTB47 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 111/217 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1038999808; called by muse, mutect2, varscan2
- ZNF546 | c.1821A>C p.K607N | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100713502, COSV61257872; called by muse, mutect2, varscan2
- ZNF594 | c.2303G>C p.R768T | Missense Mutation (SNP) | VAF 152/289 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs780718305; called by muse, mutect2, varscan2
- ZNF608 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 106/213 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs775829648; called by muse, mutect2, varscan2
- ADAMTS18 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- ALDH1L2 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); called by muse, mutect2
- ANKMY1 | c.2650G>T p.G884C | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN2 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD1E | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.196); called by muse, mutect2
- CPNE3 | c.421G>T p.V141F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- DCP1A | c.1277G>C p.G426A | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- EFCAB6 | c.1769A>C p.E590A | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FASTKD3 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXL2 | c.1013C>A p.T338N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- GPC4 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IVL | c.1593G>T p.K531N | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2
- KIAA1217 | c.4076A>G p.N1359S | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRBA | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- LRP2 | c.13333T>A p.F4445I | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAP3K12 | c.1385A>T p.Q462L | Missense Mutation (SNP) | VAF 97/171 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- MBD1 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
- MED13 | c.5164T>A p.C1722S | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- MGAM | c.2053A>T p.N685Y | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTTP | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- NIPAL1 | c.1220G>C p.R407T | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- NRP2 | c.625A>T p.K209* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- NTN5 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, varscan2
- OR2F2 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR51A4 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2
- OR5M8 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- PANK4 | c.2178G>A p.M726I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCLO | c.11927C>T p.S3976L | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- PIGQ | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- PLS3 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PTPRS | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RIPK3 | c.865A>G p.M289V | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMAD2 | c.1225A>T p.T409S | Missense Mutation (SNP) | VAF 94/170 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SMG1 | c.5443C>A p.P1815T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPATA16 | c.1100T>A p.M367K | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STAC | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TEAD4 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- TEX11 | c.1916G>A p.R639Q (on ENST00000344304; = p.R624Q on NM_031276.3) | Missense Mutation (SNP) | VAF 10/273 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- USP44 | c.138T>A p.H46Q | Missense Mutation (SNP) | VAF 122/268 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by mutect2, varscan2
- ZNF716 | c.599T>A p.L200Q | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTG1 | c.150G>A p.K50= | Silent (SNP) | VAF 156/313 reads (50%) | catalogued as rs1482374138; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCL11B | c.1767C>T p.D589= (on ENST00000357195 / NM_001282237.2; = p.D518= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/209 reads (46%) | catalogued as rs769037113; called by muse, mutect2, varscan2
- BRD1 | c.702C>T p.C234= | Silent (SNP) | VAF 117/255 reads (46%) | catalogued as rs758830099, COSV53462794; called by muse, mutect2, varscan2
- CD81 | c.636C>T p.V212= | Silent (SNP) | VAF 82/158 reads (52%) | catalogued as rs144381255; called by muse, mutect2, varscan2
- CLEC16A | c.3057C>A p.R1019= | Silent (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- DNAH8 | c.8199A>G p.P2733= | Silent (SNP) | VAF 184/308 reads (60%) | called by muse, mutect2, varscan2
- GFRA1 | c.588C>T p.L196= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV100815654, COSV62605176; called by muse, mutect2, varscan2
- GLRA4 | c.1119C>T p.F373= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV100129057; called by muse, mutect2, varscan2
- HS6ST3 | c.537G>A p.A179= | Silent (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- KRTAP13-3 | c.510T>G p.G170= | Silent (SNP) | VAF 91/195 reads (47%) | called by muse, mutect2, varscan2
- LYPD3 | c.27C>T p.A9= | Silent (SNP) | VAF 47/135 reads (35%) | called by muse, mutect2, varscan2
- MARK2 | c.1815G>A p.V605= (on ENST00000402010 / NM_001039469.2; = p.V550= on NM_004954.5) | Silent (SNP) | VAF 72/135 reads (53%) | called by muse, varscan2
- MRPL54 | c.276C>T p.Y92= | Silent (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- OR8K1 | c.111C>T p.F37= | Silent (SNP) | VAF 121/263 reads (46%) | called by muse, mutect2, varscan2
- PPP1R37 | c.2028G>A p.E676= | Silent (SNP) | VAF 70/196 reads (36%) | called by muse, mutect2, varscan2
- PROX2 | c.75C>T p.G25= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as rs1419233256, COSV71520211; called by muse, mutect2, varscan2
- RMC1 | c.1827C>T p.F609= | Silent (SNP) | VAF 8/248 reads (3%) | catalogued as rs1567937617; called by muse, mutect2
- SCN2A | c.2529G>T p.V843= | Silent (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- TTC23L | c.774C>T p.Y258= | Silent (SNP) | VAF 83/181 reads (46%) | catalogued as rs370183850; called by muse, mutect2, varscan2
- ZRANB1 | c.1065C>T p.I355= | Silent (SNP) | VAF 11/235 reads (5%) | called by muse, mutect2
- AADACL3 | c.*725C>T | 3'UTR (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- ABCB6 | c.-277G>A | 5'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- AC011503.1 | n.467+7089T>A | Intron (SNP) | VAF 8/218 reads (4%) | catalogued as rs1043275665; called by muse, mutect2
- AFAP1 | c.*3321C>A | 3'UTR (SNP) | VAF 64/132 reads (48%) | catalogued as rs1383484911, COSV61793291; called by muse, mutect2, varscan2
- ANO4 | c.-64G>A | 5'UTR (SNP) | VAF 25/401 reads (6%) | catalogued as rs565412977, COSV54598599; called by muse, mutect2
- ARHGEF37 | c.*1848G>A | 3'UTR (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- ASH1L | c.*325_*328delinsG | 3'UTR (DEL) | VAF 89/158 reads (56%) | called by pindel, varscan2*
- ATP5MC3 | c.-1G>A | 5'UTR (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- BEND2 | c.*154del | 3'UTR (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- C5orf58 | chr5:170232939 C>T | 5'Flank (SNP) | VAF 84/144 reads (58%) | called by muse, mutect2, varscan2
- CCDC113 | c.*1765G>A | 3'UTR (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- CD69 | c.388-118G>C | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- CDYL | c.*323dup | 3'UTR (INS) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- CEBPB | c.*81C>T | 3'UTR (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- CHD8 | c.*127G>A | 3'UTR (SNP) | VAF 11/49 reads (22%) | catalogued as rs1369672042; called by mutect2, varscan2
- CNTN5 | c.*422T>A | 3'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.*772C>A | 3'UTR (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- CPSF4L | c.498-1493C>A | Intron (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- CROT | c.1719-57C>T | Intron (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
- CSMD3 | c.178+59874C>A | Intron (SNP) | VAF 48/231 reads (21%) | called by muse, mutect2, varscan2
- DCC | c.*1015G>A | 3'UTR (SNP) | VAF 82/145 reads (57%) | catalogued as rs376086091; called by muse, mutect2, varscan2
- DMBT1 | c.6398-52C>A | Intron (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- EBLN2 | c.-58C>T | 5'UTR (SNP) | VAF 11/28 reads (39%) | catalogued as rs551675032; called by muse, mutect2, varscan2
- EEA1 | c.*2045G>A | 3'UTR (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- ENDOD1 | c.*1206C>A | 3'UTR (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- FGFR1OP2 | c.*1709T>C | 3'UTR (SNP) | VAF 57/120 reads (48%) | called by muse, mutect2, varscan2
- FTMT | c.-60G>A | 5'UTR (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- GABRA4 | c.*580T>A | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2
- GNE | c.51+11544C>T | Intron (SNP) | VAF 27/66 reads (41%) | catalogued as rs1453653846; called by muse, varscan2
- GOSR1 | c.*406A>G | 3'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as rs1282371996; called by muse, mutect2, varscan2
- HAPLN4 | c.*26C>T | 3'UTR (SNP) | VAF 10/27 reads (37%) | catalogued as rs1167501782; called by muse, varscan2
- HK3 | c.2054-18T>G | Intron (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- HPGD | c.421+830C>A | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- HS3ST1 | c.*2662G>T | 3'UTR (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- HTR2C | c.*1603G>A | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- IL1R1 | c.*134T>G | 3'UTR (SNP) | VAF 61/261 reads (23%) | called by muse, mutect2, varscan2
- IL22RA2 | c.*223G>A | 3'UTR (SNP) | VAF 28/140 reads (20%) | called by muse, mutect2, varscan2
- IRAG1 | c.*2832G>A | 3'UTR (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- KCNMA1 | chr10:77638012 G>T | 5'Flank (SNP) | VAF 6/32 reads (19%) | called by muse, varscan2
- MGAM | c.4618+12862A>G | Intron (SNP) | VAF 96/211 reads (45%) | catalogued as rs1284847692; called by muse, mutect2, varscan2
- MRGPRF | c.*172G>A | 3'UTR (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- MSRB1 | c.*193G>T | 3'UTR (SNP) | VAF 28/148 reads (19%) | called by muse, mutect2, varscan2
- NAXD | c.*210T>G | 3'UTR (SNP) | VAF 68/135 reads (50%) | called by muse, mutect2, varscan2
- NEBL | c.798+56del | Intron (DEL) | VAF 12/24 reads (50%) | catalogued as rs1021459295; called by mutect2, varscan2
- NINJ2 | c.-74C>T | 5'UTR (SNP) | VAF 45/95 reads (47%) | catalogued as rs552805082; called by muse, mutect2, varscan2
- NKAIN1 | c.*1067A>T | 3'UTR (SNP) | VAF 66/123 reads (54%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*2814A>G | 3'UTR (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- OR10D1P | n.720C>T | RNA (SNP) | VAF 19/26 reads (73%) | catalogued as rs772987536; called by muse, mutect2, varscan2
- PDCD2L | c.276-44G>A | Intron (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- PPP1R3B | c.*665C>T | 3'UTR (SNP) | VAF 45/96 reads (47%) | catalogued as rs1172435170; called by muse, mutect2
- PTPRG | c.*3836C>A | 3'UTR (SNP) | VAF 31/49 reads (63%) | called by muse, mutect2, varscan2
- RNF187 | c.-43C>A | 5'UTR (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- RNF217 | c.*6414A>G | 3'UTR (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- RNF220 | c.907-494G>T | Intron (SNP) | VAF 22/52 reads (42%) | called by muse, varscan2
- RPL37A | c.*86T>C | 3'UTR (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- SEL1L | c.*3049C>G | 3'UTR (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- SLC13A1 | c.99+9269C>T | Intron (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- SLC19A1 | c.*1261G>A | 3'UTR (SNP) | VAF 58/113 reads (51%) | catalogued as rs977733264; called by muse, mutect2, varscan2
- SLCO4C1 | c.*1687A>G | 3'UTR (SNP) | VAF 46/369 reads (12%) | called by muse, mutect2, varscan2
- SLF1 | c.*929G>A | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- SOCS6 | c.*1083A>C | 3'UTR (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.*986G>A | 3'UTR (SNP) | VAF 27/69 reads (39%) | catalogued as rs1469575383; called by muse, mutect2, varscan2
- SYT13 | c.*2830C>T | 3'UTR (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- TCP11X3P | n.657G>A | RNA (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- TLR4 | c.*1949G>T | 3'UTR (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
- TMEM144 | c.109+811A>C | Intron (SNP) | VAF 31/82 reads (38%) | catalogued as rs760746584; called by muse, mutect2, varscan2
- TMEM259 | c.508-47C>T | Intron (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- TRUB1 | c.523+81C>T | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- USP12 | c.*1143G>T | 3'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- XKR4 | c.806+32166T>C | Intron (SNP) | VAF 64/130 reads (49%) | called by muse, varscan2
- XKR4 | c.806+32211C>A | Intron (SNP) | VAF 60/204 reads (29%) | called by muse, varscan2
- YJU2 | chr19:4246967 G>T | 5'Flank (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- YWHAQ | c.*907A>T | 3'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- Z83844.2 | c.*202G>C | 3'UTR (SNP) | VAF 42/67 reads (63%) | called by muse, mutect2, varscan2
- ZFYVE1 | c.1636-86G>A | Intron (SNP) | VAF 36/63 reads (57%) | catalogued as rs1294443300; called by muse, mutect2
- ZNF367 | c.*1589A>C | 3'UTR (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- ZNF572 | c.*1361G>T | 3'UTR (SNP) | VAF 18/82 reads (22%) | called by muse, varscan2
- ZNF572 | c.*1407G>A | 3'UTR (SNP) | VAF 18/84 reads (21%) | called by muse, varscan2
- ZNF672 | c.*587C>A | 3'UTR (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- ZNRF1 | c.*32+131C>T | Intron (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
